Surgical pathology report (de-identified scan), TCGA case TCGA-X4-A8KS, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Institute for Medical Research, specimen TCGA-X4-A8KS-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
JW 4/4/14

----- SURGICAL PATHOLOGY -----

MEDICAL RECORD | SURGICAL PATHOLOGY

PATHOLOGY REPORT
Laboratory: Accession No.
Submitted by: Date obtained:
Specimen (Received
1. PERI-PROSTATIC FAT-
2. SUBCUTANEOUS-
3. PROSTATE
BRIEF CLINICAL HISTORY:
PREOPERATIVE DIAGNOSIS:
PROSTATE ADENOCARCINOMA
OPERATIVE FINDINGS:
POSTOPERATIVE DIAGNOSIS:
PROSTATE ADENOCARCINOMA

Surgeon/physician:

PATHOLOGY REPORT
Laboratory: Accession No.
Pathology Resident:

Gross description:

Specimen 1, "prostate." Received fresh for research tissue harvesting and placed in formalin is a 33 gram, 3.9 x 3.6 x 3.1 cm prostatectomy specimen with bilateral adnexa. The specimen is inked as follows: apex-yellow, bladder neck green, right black, and left blue. Sectioning from apex to bladder neck reveals pink-tan, spongy prostatic parenchyma with mild peri-urethral nodularity. No distinct masses are noted. The specimen is entirely sequentially submitted.

BLOCK SUMMARY:

Block 1 - right apex
Block 2-11 - right prostate
Block 12 - right bladder neck
Block 13 - right vas deferens margin and representative section of seminal vesicle
Block 14 - left apex
Block 15-26 - left prostate
Block 27 - left bladder neck
Block 28 - left vas deferens margin and representative section of seminal vesicle

Diagnosis:

PROSTATE, PROSTATECTOMY: ADENOCARCINOMA, GLEASON'S COMBINED SCORE 7 (3+4), INVOLVING BILATERAL LOBES

NO. 2: ESTIMATED TUMOR VOLUME: 5%

NO. 3: EXTRACAPSULAR EXTENSION: NOT IDENTIFIED

NO. 4: SURGICAL MARGIN: POSITIVE FOR CARCINOMA, FOCALLY NEAR THE RIGHT APEX

[page 2 of 2]
NO. 5: PERINEURAL INVASION: PRESENT

NO. 6: LYMPHOVASCULAR SPACE INVASION: NOT IDENTIFIED

NO. 7: SEMINAL VESICLES: NEGATIVE FOR CARCINOMA BILATERALLY

NO. 8: pSTAGE: T2CNXX

CPT 88309

Signed

(End of report)

Source: NCI Genomic Data Commons file 3c10ea7f-f268-494f-8272-437295e00aac (TCGA-X4-A8KS.30844429-3F9C-4AD0-8A23-64012532347C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).